Somatic mutation profile of tumor specimen TCGA-T7-A92I-01A (aliquot TCGA-T7-A92I-01A-11D-A36X-10) from TCGA case TCGA-T7-A92I, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G1; Age at diagnosis: 47.4 years (17,331 days).
Specimen TCGA-T7-A92I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22825d1a-c819-40d8-9fcf-b0043d9dfa4c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-T7-A92I-10A (Blood Derived Normal), aliquot TCGA-T7-A92I-10A-01D-A370-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/596f5861-23a3-4020-990f-79db2ee030e5

The open-access MAF lists 35 somatic variants for this specimen: 29 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 25, Silent 6, Frame Shift Del 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TSC2 | c.3610+1G>C p.X1204_splice | Splice Site (SNP) | VAF 16/53 reads (30%) | catalogued as rs45517299, CS001854, CS145290, COSV54764939, COSV99552521; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ANK2 | c.9682G>A p.V3228M | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as rs141013157; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARHGEF9 | c.1038G>C p.Q346H | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99491343; called by muse, mutect2, varscan2
- CCDC81 | c.1099C>T p.L367F (on ENST00000445632 / NM_001156474.2; = p.L277F on NM_021827.4) | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV99563890; called by muse, mutect2, varscan2
- CNTN3 | c.2887G>A p.V963M | Missense Mutation (SNP) | VAF 47/201 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV99723215; called by muse, mutect2, varscan2
- COL7A1 | c.1324C>A p.R442S | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.211); catalogued as COSV100095016; called by muse, mutect2, varscan2
- CRNKL1 | c.1506A>T p.E502D | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV101056795; called by muse, mutect2, varscan2
- EXOC4 | c.2335C>A p.H779N | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99552233; called by muse, mutect2, varscan2
- FAM214A | c.478A>G p.S160G | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99957573; called by muse, mutect2, varscan2
- KIR2DL1 | c.977C>T p.P326L | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.078); catalogued as COSV99382645; called by muse, mutect2, varscan2
- LAMTOR2 | c.343C>A p.L115M | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100737277; called by muse, mutect2, varscan2
- MFAP1 | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.398); catalogued as rs767759857, COSV99979596; called by muse, mutect2, varscan2
- NPC1L1 | c.3327A>T p.K1109N | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as COSV99202588; called by muse, mutect2
- NPHP3 | c.1448A>G p.D483G | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1476558800, COSV100446597; called by muse, mutect2, varscan2
- OR4K1 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 56/301 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs372704933; called by muse, mutect2, varscan2
- PCDHGA1 | c.133G>T p.V45L | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV100965922, COSV65295220; called by muse, mutect2, varscan2
- PTPRJ | c.4003T>A p.Y1335N | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV101394425; called by muse, mutect2, varscan2
- PTPRZ1 | c.1849A>G p.I617V | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs1363663864, COSV101099483; called by muse, mutect2, varscan2
- SEC62 | c.164G>T p.C55F | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100427884; called by muse, mutect2, varscan2
- SEMA6A | c.821C>T p.T274M | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99962771; called by muse, mutect2, varscan2
- TSC2 | c.2603T>A p.V868E | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99552520; called by muse, mutect2, varscan2
- UBOX5 | c.521G>A p.R174K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99417353; called by muse, mutect2
- UBOX5 | c.519A>T p.L173F | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV99417356; called by muse, mutect2
- ZC3H7A | c.2626A>G p.I876V | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV100865444; called by muse, mutect2, varscan2
- ZNF528 | c.912G>T p.K304N | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100846611; called by muse, mutect2, varscan2
- BUB1B | c.307_329del p.E103Rfs*7 | Frame Shift Del (DEL) | VAF 20/66 reads (30%) | called by mutect2, pindel, varscan2
- CWC25 | c.777A>T p.R259S | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- DGCR2 | c.31dup p.L11Pfs*42 | Frame Shift Ins (INS) | VAF 18/82 reads (22%) | called by mutect2, pindel, varscan2
- ZNF791 | c.1627del p.T543Qfs*25 | Frame Shift Del (DEL) | VAF 53/196 reads (27%) | called by mutect2, pindel, varscan2
- ABCG8 | c.36G>A p.P12= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as rs368998235; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRCA2 | c.10173C>T p.I3391= | Silent (SNP) | VAF 25/80 reads (31%) | catalogued as COSV100582998; called by muse, mutect2, varscan2
- PPP4R3B | c.2121A>G p.K707= (on ENST00000616407 / NM_001122964.3; = p.K622= on NM_020463.4) | Silent (SNP) | VAF 69/211 reads (33%) | catalogued as COSV99701368; called by muse, mutect2, varscan2
- SEPTIN2 | c.120G>A p.L40= | Silent (SNP) | VAF 17/49 reads (35%) | catalogued as COSV100764908; called by muse, mutect2, varscan2
- TMEM174 | c.603T>C p.S201= | Silent (SNP) | VAF 56/170 reads (33%) | catalogued as COSV99703694; called by muse, mutect2, varscan2
- TTN | c.73587T>G p.G24529= (on ENST00000591111; = p.G17105= on NM_003319.4) | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as COSV59878631; called by muse, mutect2, varscan2
